Somatic mutation profile of tumor specimen MMRF_2563_1_BM_CD138pos (aliquot MMRF_2563_1_BM_CD138pos_T1_KHS5U_K15174) from MMRF case MMRF_2563, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 62.1 years (22,698 days).
Specimen MMRF_2563_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b0654d9d-c2d1-40b6-8b91-9588cad8cfd5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2563_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2563_1_PB_Whole_C2_KHS5U_K15173; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/61c675cc-2c1e-4490-b3f7-bf75b2bf5e56

The open-access MAF lists 109 somatic variants for this specimen: 49 protein-altering or splice-affecting, 10 silent, 50 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 46, 3'UTR 32, Silent 10, Intron 6, 5'UTR 4, 3'Flank 3, 5'Flank 3, Nonsense Mutation 2, RNA 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCG5 | c.406G>A p.D136N | Missense Mutation (SNP) | VAF 29/53 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as rs746174960; called by muse, mutect2, varscan2
- CPSF1 | c.4067A>T p.Y1356F | Missense Mutation (SNP) | VAF 48/106 reads (45%) | SIFT deleterious (0.05); PolyPhen benign (0.282); catalogued as COSV100450266; called by muse, mutect2, varscan2
- CXCR4 | c.74A>G p.K25R | Missense Mutation (SNP) | VAF 139/269 reads (52%) | SIFT tolerated (0.44); PolyPhen benign (0.216); catalogued as rs1387554691; called by muse, mutect2, varscan2
- EPHB3 | c.2437C>T p.R813W | Missense Mutation (SNP) | VAF 71/140 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs374567246; called by muse, mutect2, varscan2
- FILIP1 | c.3032C>T p.T1011M | Missense Mutation (SNP) | VAF 74/164 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); catalogued as rs201450409, COSV52727046; called by muse, mutect2, varscan2
- HECW1 | c.166G>T p.G56C | Missense Mutation (SNP) | VAF 84/171 reads (49%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.818); catalogued as COSV101223304; called by muse, mutect2, varscan2
- IGHV1-69 | c.125A>G p.K42R | Missense Mutation (SNP) | VAF 15/15 reads (100%) | SIFT deleterious (0.04); PolyPhen benign (0.246); catalogued as rs555431911; called by mutect2, varscan2
- IGKV4-1 | c.182G>C p.W61S | Missense Mutation (SNP) | VAF 56/59 reads (95%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778196241; called by muse, mutect2, varscan2
- IGKV4-1 | c.183G>A p.W61* | Nonsense Mutation (SNP) | VAF 56/59 reads (95%) | catalogued as rs151106836; called by muse, mutect2, varscan2
- IGKV4-1 | c.292A>T p.T98S | Missense Mutation (SNP) | VAF 28/28 reads (100%) | SIFT tolerated (0.07); PolyPhen benign (0.425); catalogued as rs367827041; called by muse, varscan2
- IGKV4-1 | c.350A>G p.Y117C | Missense Mutation (SNP) | VAF 32/32 reads (100%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.756); catalogued as rs371099186; called by muse, varscan2
- KIF19 | c.476G>A p.R159Q | Missense Mutation (SNP) | VAF 50/97 reads (52%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.782); catalogued as rs749729692; called by muse, mutect2, varscan2
- L1TD1 | c.1480A>G p.T494A | Missense Mutation (SNP) | VAF 69/133 reads (52%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.506); catalogued as rs1323839412; called by muse, mutect2
- NEB | c.7667G>A p.R2556H | Missense Mutation (SNP) | VAF 24/221 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs764471883, COSV51458146; called by muse, mutect2, varscan2
- NF1 | c.5744T>A p.L1915Q (on ENST00000358273 / NM_001042492.3; = p.L1894Q on NM_000267.3) | Missense Mutation (SNP) | VAF 68/71 reads (96%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM143450; called by muse, mutect2, varscan2
- NSD2 | c.226G>T p.A76S | Missense Mutation (SNP) | VAF 69/146 reads (47%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs770395467; called by muse, mutect2, varscan2
- NXPH1 | c.301C>T p.R101W | Missense Mutation (SNP) | VAF 49/193 reads (25%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.981); catalogued as rs1274208163, COSV101339717; called by muse, mutect2, varscan2
- OR4K1 | c.235C>T p.P79S | Missense Mutation (SNP) | VAF 66/300 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); catalogued as rs1350015141; called by muse, mutect2, varscan2
- PDE1B | c.1235G>A p.R412H | Missense Mutation (SNP) | VAF 61/163 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54489425; called by muse, mutect2, varscan2
- POLD1 | c.1873G>A p.G625R | Missense Mutation (SNP) | VAF 73/144 reads (51%) | SIFT tolerated (0.17); PolyPhen benign (0.052); catalogued as rs1060501836; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PRMT8 | c.784A>G p.I262V | Missense Mutation (SNP) | VAF 82/192 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1189382000; called by muse, mutect2, varscan2
- SLFN11 | c.1325C>T p.S442F | Missense Mutation (SNP) | VAF 78/170 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as rs760558446; called by muse, mutect2, varscan2
- SPEG | c.9058G>A p.E3020K | Missense Mutation (SNP) | VAF 43/91 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as rs368875454; called by muse, mutect2, varscan2
- SPTBN2 | c.1973G>A p.R658Q | Missense Mutation (SNP) | VAF 59/107 reads (55%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as rs753491527; ClinVar: likely benign; called by muse, mutect2, varscan2
- TDRD15 | c.2554C>T p.R852C | Missense Mutation (SNP) | VAF 60/126 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs778497547; called by muse, mutect2, varscan2
- TMEM126B | c.366C>G p.D122E | Missense Mutation (SNP) | VAF 36/85 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.024); catalogued as rs1165237226; called by muse, mutect2, varscan2
- USP42 | c.2939G>A p.R980Q | Missense Mutation (SNP) | VAF 40/73 reads (55%) | SIFT tolerated (0.12); PolyPhen benign (0.019); catalogued as rs1208316302; called by muse, mutect2, varscan2
- BEND4 | c.58C>A p.Q20K | Missense Mutation (SNP) | VAF 42/99 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- CD180 | c.61A>T p.I21F | Missense Mutation (SNP) | VAF 60/120 reads (50%) | SIFT tolerated (0.11); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- CDK13 | c.2123T>C p.I708T | Missense Mutation (SNP) | VAF 88/175 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- CHFR | c.102G>T p.R34S | Missense Mutation (SNP) | VAF 39/69 reads (57%) | SIFT tolerated (0.4); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- CLUH | c.2962A>C p.K988Q (on ENST00000435359; = p.K1027Q on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 53/117 reads (45%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.616); called by muse, mutect2, varscan2
- CPSF1 | c.3937A>G p.R1313G | Missense Mutation (SNP) | VAF 102/216 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- ELMO2 | c.409A>G p.T137A | Missense Mutation (SNP) | VAF 56/120 reads (47%) | SIFT tolerated (0.44); PolyPhen benign (0.005); called by muse, mutect2
- ERICH3 | c.782C>T p.T261I | Missense Mutation (SNP) | VAF 39/91 reads (43%) | SIFT tolerated (0.37); PolyPhen benign (0.147); called by muse, mutect2, varscan2
- FAT2 | c.69A>C p.E23D | Missense Mutation (SNP) | VAF 92/169 reads (54%) | SIFT tolerated (0.07); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- FNDC7 | c.1937T>C p.I646T | Missense Mutation (SNP) | VAF 44/109 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- IGHV2-70D | c.286A>T p.K96* | Nonsense Mutation (SNP) | VAF 36/40 reads (90%) | called by muse, varscan2
- IGKV4-1 | c.323A>C p.D108A | Missense Mutation (SNP) | VAF 33/33 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- IZUMO3 | c.595A>G p.I199V (on ENST00000543880 / NM_001365008.2; = p.I193V on NM_001271706.1) | Missense Mutation (SNP) | VAF 100/206 reads (49%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- KCNH5 | c.1945G>A p.V649I | Missense Mutation (SNP) | VAF 39/113 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- KLF3 | c.380T>C p.M127T | Missense Mutation (SNP) | VAF 119/252 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- MACF1 | c.21425G>A p.G7142E (on ENST00000372915; = p.G5187E on NM_012090.5) | Missense Mutation (SNP) | VAF 100/217 reads (46%) | called by muse, mutect2, varscan2
- MROH9 | c.2572G>A p.D858N | Missense Mutation (SNP) | VAF 22/36 reads (61%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.189); called by muse, mutect2, varscan2
- MUC16 | c.16580G>A p.S5527N | Missense Mutation (SNP) | VAF 82/153 reads (54%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRUNE2 | c.6360C>A p.H2120Q | Missense Mutation (SNP) | VAF 33/68 reads (49%) | SIFT tolerated (0.06); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- RIMKLA | c.208G>C p.V70L | Missense Mutation (SNP) | VAF 92/199 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- SLCO1C1 | c.338G>T p.G113V | Missense Mutation (SNP) | VAF 122/278 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- UBQLN1 | c.1618-1G>A p.X540_splice | Splice Site (SNP) | VAF 19/55 reads (35%) | called by muse, mutect2, varscan2
- AQP2 | c.700C>T p.L234= | Silent (SNP) | VAF 28/70 reads (40%) | called by muse, mutect2, varscan2
- ARID1B | c.1488G>A p.R496= | Silent (SNP) | VAF 44/80 reads (55%) | catalogued as rs759078059; called by muse, mutect2, varscan2
- EEPD1 | c.1590A>G p.E530= | Silent (SNP) | VAF 32/74 reads (43%) | called by muse, varscan2
- EFHD2 | c.153G>C p.A51= | Silent (SNP) | VAF 28/68 reads (41%) | catalogued as rs1307206028; called by muse, mutect2, varscan2
- GALNT9 | c.1386C>T p.T462= (on ENST00000328957 / NM_001122636.2; = p.T96= on NM_021808.3) | Silent (SNP) | VAF 51/100 reads (51%) | catalogued as rs750649859; called by muse, mutect2, varscan2
- GATA4 | c.1074C>T p.S358= | Silent (SNP) | VAF 83/177 reads (47%) | catalogued as rs375407669, CD041915; ClinVar: likely benign; called by muse, mutect2, varscan2
- MGST1 | c.162C>A p.G54= | Silent (SNP) | VAF 67/149 reads (45%) | called by muse, mutect2, varscan2
- PEG3 | c.1140C>G p.T380= | Silent (SNP) | VAF 143/279 reads (51%) | catalogued as COSV55631419; called by muse, mutect2, varscan2
- PFKFB4 | c.612G>A p.S204= | Silent (SNP) | VAF 121/225 reads (54%) | catalogued as rs137967133; called by muse, mutect2, varscan2
- ZNF318 | c.4458C>T p.L1486= | Silent (SNP) | VAF 43/108 reads (40%) | catalogued as rs1376441107; called by muse, mutect2, varscan2
- AFMID | c.*266G>A | 3'UTR (SNP) | VAF 93/176 reads (53%) | called by muse, mutect2, varscan2
- ATL3 | chr11:63671869 T>G | 5'Flank (SNP) | VAF 45/97 reads (46%) | called by muse, mutect2, varscan2
- AZIN2 | c.-72-97C>T | Intron (SNP) | VAF 10/19 reads (53%) | called by muse, varscan2
- BCL7A | chr12:122021411 G>C | 5'Flank (SNP) | VAF 72/137 reads (53%) | catalogued as COSV55846921, COSV55847077; called by muse, mutect2, varscan2
- BMP10 | c.*124C>T | 3'UTR (SNP) | VAF 24/50 reads (48%) | called by muse, mutect2, varscan2
- C8orf34 | c.1549+13T>C | Intron (SNP) | VAF 58/125 reads (46%) | called by muse, mutect2, varscan2
- CCDC58 | c.*93T>G | 3'UTR (SNP) | VAF 99/221 reads (45%) | called by muse, mutect2, varscan2
- CDH9 | c.*261T>A | 3'UTR (SNP) | VAF 53/89 reads (60%) | called by muse, mutect2, varscan2
- CDON | c.*3648G>A | 3'UTR (SNP) | VAF 69/142 reads (49%) | called by muse, mutect2, varscan2
- CHRM3 | c.*1093_*1096del | 3'UTR (DEL) | VAF 3/28 reads (11%) | catalogued as rs367567825; called by pindel, varscan2*
- COL4A4 | c.*3058A>G | 3'UTR (SNP) | VAF 57/133 reads (43%) | called by muse, mutect2, varscan2
- CSMD1 | c.*189C>A | 3'UTR (SNP) | VAF 74/178 reads (42%) | called by muse, mutect2, varscan2
- DNM3 | chr1:172411581 T>G | 3'Flank (SNP) | VAF 29/51 reads (57%) | called by muse, mutect2, varscan2
- DSC2 | c.*412T>G | 3'UTR (SNP) | VAF 57/119 reads (48%) | called by muse, mutect2, varscan2
- EEF1A2 | c.-59C>G | 5'UTR (SNP) | VAF 12/23 reads (52%) | called by muse, mutect2, varscan2
- EEPD1 | c.*52A>G | 3'UTR (SNP) | VAF 65/141 reads (46%) | called by muse, mutect2, varscan2
- EIF2S3B | c.*251T>C | 3'UTR (SNP) | VAF 19/38 reads (50%) | called by muse, mutect2, varscan2
- ELL3 | c.168+65T>C | Intron (SNP) | VAF 80/157 reads (51%) | called by muse, mutect2, varscan2
- ELP4 | chr11:31786859 A>C | 3'Flank (SNP) | VAF 40/86 reads (47%) | called by muse, mutect2, varscan2
- EPG5 | c.*316C>G | 3'UTR (SNP) | VAF 12/58 reads (21%) | called by muse, mutect2, varscan2
- FAM217B | c.*3038A>C | 3'UTR (SNP) | VAF 26/69 reads (38%) | called by muse, mutect2, varscan2
- FKBP14 | c.*4064G>A | 3'UTR (SNP) | VAF 31/90 reads (34%) | catalogued as rs959089962; called by muse, mutect2, varscan2
- GABRB2 | c.-115T>C | 5'UTR (SNP) | VAF 48/112 reads (43%) | called by muse, mutect2, varscan2
- GCSAML | c.*1626A>G | 3'UTR (SNP) | VAF 9/18 reads (50%) | catalogued as COSV63577945; called by muse, mutect2, varscan2
- HECW2 | c.*720G>A | 3'UTR (SNP) | VAF 25/62 reads (40%) | called by muse, mutect2, varscan2
- KCTD16 | c.*1552C>T | 3'UTR (SNP) | VAF 33/74 reads (45%) | catalogued as rs117108089; called by muse, mutect2, varscan2
- KLHDC7A | c.*470C>A | 3'UTR (SNP) | VAF 23/60 reads (38%) | called by muse, mutect2, varscan2
- KMT2A | c.432+10913T>G | Intron (SNP) | VAF 22/53 reads (42%) | called by muse, mutect2, varscan2
- KRTAP8-1 | c.*295T>C | 3'UTR (SNP) | VAF 17/38 reads (45%) | catalogued as rs1161073517; called by muse, mutect2, varscan2
- MICAL3 | c.*2761A>G | 3'UTR (SNP) | VAF 36/37 reads (97%) | called by muse, mutect2
- MORF4 | n.428T>C | RNA (SNP) | VAF 65/145 reads (45%) | called by muse, mutect2, varscan2
- MTMR2 | c.*2184C>A | 3'UTR (SNP) | VAF 31/82 reads (38%) | catalogued as rs1028186774; called by muse, mutect2, varscan2
- MTNR1B | c.*381C>A | 3'UTR (SNP) | VAF 12/230 reads (5%) | called by muse, mutect2
- MXD3 | chr5:177306808 C>G | 3'Flank (SNP) | VAF 52/99 reads (53%) | called by muse, mutect2, varscan2
- MYOCD | c.*5206A>G | 3'UTR (SNP) | VAF 15/24 reads (63%) | called by muse, mutect2, varscan2
- NKX3-2 | c.-13G>A | 5'UTR (SNP) | VAF 21/39 reads (54%) | called by muse, mutect2, varscan2
- PDK1 | c.*142C>G | 3'UTR (SNP) | VAF 31/62 reads (50%) | called by muse, mutect2, varscan2
- PHLDB2 | c.1719+450T>G | Intron (SNP) | VAF 31/64 reads (48%) | called by muse, mutect2, varscan2
- PIGO | c.*230C>T | 3'UTR (SNP) | VAF 55/105 reads (52%) | called by muse, mutect2, varscan2
- PSMD6 | c.827-38_827-37del | Intron (DEL) | VAF 24/64 reads (38%) | called by mutect2, pindel, varscan2
- REG3A | c.*204A>C | 3'UTR (SNP) | VAF 24/49 reads (49%) | called by muse, mutect2, varscan2
- RPL14P1 | n.76G>A | RNA (SNP) | VAF 75/153 reads (49%) | catalogued as rs543537988; called by muse, mutect2, varscan2
- SAMD5 | c.*5440G>C | 3'UTR (SNP) | VAF 25/53 reads (47%) | called by muse, mutect2, varscan2
- SEC63 | c.*1199G>A | 3'UTR (SNP) | VAF 31/73 reads (42%) | called by muse, mutect2, varscan2
- SLC7A11 | c.*2793_*2799del | 3'UTR (DEL) | VAF 24/53 reads (45%) | called by mutect2, pindel, varscan2
- TIAM1 | c.*1889T>A | 3'UTR (SNP) | VAF 176/335 reads (53%) | catalogued as COSV99733285; called by muse, mutect2, varscan2
- TMEM132E | chr17:34577046 G>A | 5'Flank (SNP) | VAF 63/139 reads (45%) | called by muse, mutect2, varscan2
- TMEM235 | c.*46G>A | 3'UTR (SNP) | VAF 55/132 reads (42%) | catalogued as rs1025519194; called by muse, mutect2, varscan2
- TRAF3IP1 | c.*110C>T | 3'UTR (SNP) | VAF 34/69 reads (49%) | called by muse, mutect2, varscan2
- VPS37B | c.-56G>A | 5'UTR (SNP) | VAF 26/44 reads (59%) | called by muse, mutect2, varscan2
